Surgical pathology report (de-identified scan), TCGA case TCGA-2L-AAQJ, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Technical University of Munich, specimen TCGA-2L-AAQJ-01A (Primary Tumor).

[page 1 of 3]
Age: female

Surgery date:

Macroscopic evaluation

1. Tissue root of the mesentery: unfixed, tissue specimens 0.2 cm
2. Colon meso: unfixed, irregular specimen 0.5 cm
3. Tissue root of the mesentery: unfixed 1.5 cm large fatty tissue specimen
4. A. gastroepiploicae: unfixed, tissue specime 0.3 cm
5. A. hepatica: unfixed, a 1.4 cm large lymph node with sparcely attached soft tissue
6. Ligamentum hepato duodenale: unfixed, 2x2x1 cm large fatty tissue specimen with two lymph nodes
7. Arteria mesenterica superior: unfixed, two specimens max. 0.5 cm
8. Resection margin pancreas: unfixed, a 4x1.5x0.3 cm large tissue lamellae
9. Intraaortokaval: unfixed, fragmented grey-white indurated tissue, max. 2 cm large
10. Resection margin pancreas: unfixed, a 3x1.5x0.5 cm large pancreas specimens at one side marked with a stich
11. Gall bladder: fixed, a 6x4.5x3 cm large gall bladder, resected at the D. cysticus after 0.6 cm. The mucosa yellow-brown with multiple, max. 0.8 cm large ulcers. The wall layers widened to max. 0.6 cm, partially grey/glass-like edematous, partially hemorrhagic. At the D. cysticus a 0.8 cm large lymph node.
12. Additional resection specimen small intestine: fixed, a 15 cm long resection specimen of the small intestine, at one side closed with a clamp. At the opposite side the wall with an extension of 1.5x1.0 cm indurated. The mucosa on all sides soft. Serosa with large adhesive strands.
- A. Resection margin 1 (closed with a clamp)
- B. Resection margin 2 (opposite to the clamp)
- C. central
13. A. mesenterica superior: fixed, three max. 2x0.8x0.8 cm large fatty tissue and muscle specimens with vessels. Completely embedded.
14. Hemicolectomy right: fixed, a right hemicolectomy resection specimen, composed of a 5 cm long terminal ileum and a 26 cm long cecum/colon ascendens/transversum, mesocolic fatty tissue max. 3 cm wide. The serosa with large adhesive strands. The mucosa at the right colon flexure in a length of 4.5 cm dark red, otherwise the mucosa regular. Attached omentum majus 8x5x1.5 cm with large hemorrhages. Appendix veriformis 5 cm long without tumor.
- A. ileocecal valve
- B. colon ascendens
- C. colon flexure right
- D. Adhesions of the serosa colon ascendens
- E. Adhesions of the serosa colon flexure
- F. Adhesions of the serosa colon transversum
- G. Appendix vermiformis and omentum majus
- H. Resection margin oral
- J. Resection margin aboral and deep resection margin
15. Tissue root of the mesentery: fixed, four max. 0.6 cm large soft tissue resection specimens
16. Lig. Hepatoduodenale: fixed, a max. 0.9 cm large indurated soft tissue specimen, cut into two halves and then completely embedded.
17. Pancreas: fixed, Whipple resection specimen, composed of a 10 cm long duodenum and 3 cm wide distal stomach, a 8.5x6.5x3 cm large pancreas head. Ductus choledochus resected after 6 cm. Within the pancreas a max. 3 cm large diffusely defined solid tumor, that reaches extensively to the resection

ICD-O-3

Adenocarcinoma, duct NOS 8500L3
Sater. Pancreas head C25.0
JH 6/5/14

[page 2 of 3]
margin of the distal pancreas. The tumor is macroscopically hardly defined from the dorsal and medial resection margin. The Ductus choledochus crosses the tumor, fixed with a stent. The

tumor is macroscopically hardly defined from the duodenal wall. The gastric mucosa is edematous. The specimen is surrounded by extensive adhesions. Ink mark: medial green, dorsal black. Within the max. 2 cm wide peripancreatic fatty tissue single max. 0.8 cm large lymph nodes.

A. Ductus choledochus pre-ampullic/tumor/duodenum/resection margin medial (green)

B. Ductus choledochus (2 cm in front of the papillae)

C. + D. Tumor/stomach

E. + F. peripancreatic lymph nodes

G. Resection margin stomach and duodenum

H.+J. Resection margin Ductus choledochus (tangential)

Instantaneous section report

1., 2. Without tumor

3. negative

4. without tumor

5. a lymph node without tumor

6. negative

7. Positive (adenocarcinoma)

8. + 9. Positive (adenocarcinoma)

10. High grade PIN at the D. pancreaticus with defined tumor infiltrates

Processed: 10x instantaneous sections, 40 blocks, H&E, EvG, PAS

Microscopy

1. and 2. Using paraffin material fatty tissue without tumor with fibrosis

3. and 4. Using paraffin material fatty tissue without tumor and connective tissue

5. using paraffin material a lymph node without tumor with sinus histiocytosis

6. using paraffin material soft tissue without tumor with nerve structures. In addition, a lymph node without tumor.

7. Using paraffin material fibro-muscular tissue with infiltrates of an adenocarcinoma (see 17.)

8. and 9. Also infiltrates of carcinoma. In the additionally analyzed paraffin material two further lymph nodes without tumor.

10. Using paraffin material there is a severe atypical intraductal proliferation of the epithelium with papillary partially complex architecture. Clearly enlarged nuclei and intraepithelial mitoses. Similar as described in the instantaneous section two small carcinoma infiltrates directly adjacent.

11. The gall bladder mucosa edematous, partially atrophic, with dense chronic inflammation. At the epithelium not atypical. Within the wall partial large inflammation with lymphocytes and granulocytes and foreign body reaction. No tumor infiltrates. Fibrosis, edema, and chronic inflammation at the ductus cysticus. The hilus lymph node with follicle hyperplasia, without tumor.

12. Resection margin 1 shows duodenum without tumor. At the opposite resection margin extensive infiltration of a ductal adenocarcinoma, infiltrating within the wall to the serosa. The central specimen without tumor

13. Soft tissue and connective tissue with vessels and nerves. At multiple sites detection of perineural invasion and some tumor infiltrates in sclerotic tissue areas. Six lymph nodes without tumor.

14. At the adhesions of the serosa, that were macroscopically described, a partially lymphocytic, partially granulocyte-based inflammation with fibrin exudation and adjacent fibroblastic proliferation. Tissue

[page 3 of 3]
edema within the fatty tissue. The blood vessels are congested. The mucosa partially edematous, specifically in the ileum with hyperplasia of the Peyer's Plaques. No evidence of cancer infiltrates. The appendix is regular.

15. Fatty tissue and fibrosis with parts of 4 lymph nodes without tumor.

16. Four lymph nodes without tumor with follicle hyperplasia.

17. There are extensive infiltrates of a ductal adenocarcinoma, moderately differentiated, with enlarged nuclei and prominent nucleoli, overall a homogenous impression. Extensive stroma desmoplasia.

Frequent small necrotic areas. The tumor surrounds the Ductus choledochus as described macroscopically. The tumor infiltrates the duodenal wall. The Ductus pancreaticus extensively surrounded by the tumor. Frequent large areas of sclerosis. Extensive perineural invasion. Tumor is detected at the medial resection margin. The resection margins of the Ductus choledochus and stomach and duodenum all are without tumor. Seven peripancreatic lymph nodes without tumor.

Short report on diagnostic findings

1.-17. Extended moderately differentiated ductal adenocarcinoma of the pancreas, with infiltration of the duodenal wall (17.). Tumor is present in the resected loop of the small intestine (12.) and in the separated received resection specimens of the A. mesenterica superior (7.) and intraaortocaval (9). Tumor is present at the medial resection margin of the Whipple specimen (17.) and at the resection margin of the pancreas parenchyma (8., 10.). No evidence for lymph node metastasis. Tissue root of the mesentery without tumor (1., 3.), colon meso without tumor, A. gastroepiploicae without tumor (4.). gall bladder without tumor (11.) with acute absceding cholecystitis with cholecystolithiasis with focal fibrotic-purulent peritonitis (11.). Detection of an ischemic injury of the colon at the right colon flexure with segmental mucosa ischemia (14.).

TNM classification (UICC, 7th Edition 2010): pT4, pN0 (0/21)

Grading: G2

Resection status: R1

Source: NCI Genomic Data Commons file cb735343-f1d6-422d-a71c-255504848711 (TCGA-2L-AAQJ.6809B31A-DBAA-4F82-AD24-54F77A191076.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).